Somatic mutation profile of tumor specimen MP2PRT-PAPVTA-TMP1-A (aliquot MP2PRT-PAPVTA-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPVTA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,020 days).
Specimen MP2PRT-PAPVTA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cfd27d6-5aec-4f4c-93df-0e0be1911cc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVTA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVTA-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a179ec41-d30f-488b-a1ca-a0fdb12c9e99

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 119/286 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC010255.2 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs1392666666; called by muse, mutect2, varscan2
- TBX3 | c.1693G>A p.A565T (on ENST00000257566 / NM_016569.4; = p.A545T on NM_005996.4) | Missense Mutation (SNP) | VAF 243/530 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs767500073, COSV57474103; called by muse, mutect2, varscan2
- MAP1B | c.6523G>A p.D2175N | Missense Mutation (SNP) | VAF 187/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- POTEF | c.2846C>T p.T949I | Missense Mutation (SNP) | VAF 105/422 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- POTEI | c.2846C>T p.T949I | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFHX2 | c.6578C>G p.P2193R | Missense Mutation (SNP) | VAF 199/600 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CSMD2 | c.2229C>T p.S743= | Silent (SNP) | VAF 110/265 reads (42%) | catalogued as rs763984340, COSV53902471; called by muse, mutect2, varscan2
